Somatic mutation profile of tumor specimen TCGA-09-1675-01B (aliquot TCGA-09-1675-01B-01W-0633-09) from TCGA case TCGA-09-1675, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 50.9 years (18,596 days).
Specimen TCGA-09-1675-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39e1bd9a-d33a-4f44-87d7-3e571af4a153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1675-10A (Blood Derived Normal), aliquot TCGA-09-1675-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32a3c0b7-87cd-4c8a-a387-ef3f8c9b59c0

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, In Frame Del 4, RNA 3, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.530_535del p.P177_H178del | In Frame Del (DEL) | VAF 48/65 reads (74%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAM7 | c.1152T>G p.D384E | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV51545502; called by muse, mutect2, varscan2
- ADNP | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 146/308 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62426597; called by muse, mutect2, varscan2
- ATRNL1 | c.1625A>T p.N542I | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100744615; called by muse, mutect2
- AVPR2 | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD972997, COSV100509452; called by muse, mutect2
- C10orf71 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60511716; called by muse, mutect2, varscan2
- CACNA1B | c.5505G>T p.K1835N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53142902, COSV53143826; called by muse, mutect2, varscan2
- CAD | c.1754C>G p.T585S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53029342; called by muse, mutect2, varscan2
- CCDC85A | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV68149941, COSV68154837; called by muse, mutect2, varscan2
- CDCP1 | c.2291C>A p.P764Q | Missense Mutation (SNP) | VAF 182/350 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56107515; called by muse, mutect2, varscan2
- CFAP65 | c.5266G>T p.G1756W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV58561521; called by muse, mutect2, varscan2
- CPXM1 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs538584869, COSV101013695; called by muse, mutect2, varscan2
- CUL9 | c.2469T>G p.F823L | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99335088; called by muse, mutect2, varscan2
- CUL9 | c.2470G>T p.D824Y | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52728909; called by muse, mutect2, varscan2
- DCLRE1B | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.11); catalogued as COSV65813494; called by muse, mutect2, varscan2
- DEPDC7 | c.637C>G p.Q213E (on ENST00000241051 / NM_001077242.2; = p.Q204E on NM_139160.2) | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53808980; called by muse, mutect2, varscan2
- ENOX1 | c.1830G>T p.L610F | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV54914685; called by muse, mutect2, varscan2
- EPHA10 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60405151; called by muse, mutect2, varscan2
- ERCC6 | c.3546G>T p.K1182N | Missense Mutation (SNP) | VAF 67/1112 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs769594258, COSV100875808; called by muse, mutect2
- FAT4 | c.10142G>T p.G3381V | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58703542; called by muse, mutect2, varscan2
- FBXO11 | c.755A>G p.H252R (on ENST00000403359 / NM_001190274.2; = p.H168R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/159 reads (63%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.599); catalogued as COSV57025047; called by muse, mutect2, varscan2
- GFAP | c.1291+1G>A p.X431_splice (on ENST00000253408 / NM_001363846.2; = p.G431D on NM_001131019.3) | Splice Site (SNP) | VAF 49/58 reads (84%) | catalogued as rs1308447879, COSV99493137; called by muse, mutect2, varscan2
- GOLGA3 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.04); catalogued as COSV52641170; called by muse, mutect2, varscan2
- GPR1 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 258/277 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV67977367; called by muse, mutect2, varscan2
- GPR85 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV51785022; called by muse, mutect2, varscan2
- HMCN1 | c.3619G>T p.G1207C | Missense Mutation (SNP) | VAF 74/83 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV54932773; called by muse, mutect2, varscan2
- KIAA1549 | c.3013C>A p.P1005T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54305612, COSV54325215; called by muse, mutect2, varscan2
- LY75 | c.196T>A p.L66I | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV55111849; called by muse, mutect2, varscan2
- MYH15 | c.5588C>A p.T1863N | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV56317697; called by muse, mutect2, varscan2
- NRG1 | c.1804A>T p.T602S (on ENST00000405005 / NM_013964.5; = p.T607S on NM_013956.5) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as COSV55172952; called by muse, mutect2, varscan2
- OR10J3 | c.540_577del p.D181Hfs*4 | Frame Shift Del (DEL) | VAF 112/307 reads (36%) | catalogued as COSV59955447; called by mutect2, pindel, varscan2
- OR10S1 | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as COSV73343003; called by muse, mutect2, varscan2
- OR14A16 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62927341; called by muse, mutect2, varscan2
- OR2B3 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1429492425, COSV65851151; called by muse, mutect2, varscan2
- PCDHA1 | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as COSV65376382; called by muse, mutect2, varscan2
- PDE6C | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117312; called by muse, mutect2, varscan2
- PIK3C2G | c.1611A>C p.E537D | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV56828334; called by muse, mutect2, varscan2
- PPP2R1B | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV59537284; called by muse, mutect2, varscan2
- PROKR2 | c.1037A>T p.K346M | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV54088764; called by muse, mutect2, varscan2
- REPS2 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV58187101; called by muse, mutect2, varscan2
- RIMBP2 | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55482083; called by muse, mutect2, varscan2
- SDHAF4 | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 87/178 reads (49%) | catalogued as COSV65085564; called by muse, mutect2, varscan2
- SETD1A | c.3199G>T p.E1067* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV52691639; called by muse, mutect2, varscan2
- SPOCK1 | c.970A>T p.S324C | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV56462803; called by muse, mutect2, varscan2
- TCP11L1 | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 166/520 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57517323; called by muse, mutect2, varscan2
- THAP4 | c.400A>C p.N134H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.204); catalogued as COSV101126014; called by muse, mutect2, varscan2
- TMEM132B | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV54742514; called by muse, mutect2, varscan2
- TRAPPC9 | c.1680G>C p.L560F | Missense Mutation (SNP) | VAF 216/338 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV66908130; called by muse, mutect2, varscan2
- UGT2B11 | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 265/577 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as rs751649625, COSV71422996, COSV71424176; called by muse, mutect2, varscan2
- WARS1 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV59927147; called by muse, mutect2, varscan2
- ZNF106 | c.3254A>C p.Y1085S | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55520998; called by muse, mutect2, varscan2
- EPOR | c.1127_1156del p.L376_L385del | In Frame Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- GCKR | c.1191_1199del p.P398_L400del | In Frame Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- NBPF11 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 73/393 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PODN | c.1790_1804del p.K597_L601del (on ENST00000395871; = p.K549_L553del on NM_153703.5 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CAMTA1 | c.240T>C p.I80= | Silent (SNP) | VAF 126/134 reads (94%) | catalogued as rs749758954, COSV57922004; called by muse, mutect2, varscan2
- DNAH9 | c.12135G>A p.T4045= | Silent (SNP) | VAF 275/314 reads (88%) | catalogued as rs374717515; called by muse, mutect2, varscan2
- FOXK2 | c.600C>A p.P200= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs201972160, COSV100082057, COSV58882088; called by muse, mutect2, varscan2
- GRIK2 | c.330A>T p.S110= | Silent (SNP) | VAF 214/444 reads (48%) | catalogued as COSV59712751, COSV59763174; called by muse, mutect2, varscan2
- LRP2 | c.13557A>T p.I4519= | Silent (SNP) | VAF 65/227 reads (29%) | catalogued as COSV55569532; called by muse, mutect2, varscan2
- OR10J3 | c.747C>T p.V249= | Silent (SNP) | VAF 130/301 reads (43%) | catalogued as COSV59955443; called by muse, mutect2, varscan2
- PPP2R2C | c.432G>A p.T144= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as rs144455156; called by muse, mutect2, varscan2
- PXDNL | c.3813C>A p.V1271= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV62496531; called by muse, mutect2, varscan2
- RIMBP3 | c.2778G>T p.L926= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- SATB1 | c.1785G>A p.Q595= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV58672153; called by muse, mutect2, varscan2
- TAS1R2 | c.495C>T p.S165= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as rs759207242, COSV64743453; called by muse, mutect2, varscan2
- UBTD2 | c.468G>A p.L156= | Silent (SNP) | VAF 251/276 reads (91%) | catalogued as COSV67143865; called by muse, mutect2, varscan2
- VCAN | c.144G>A p.T48= | Silent (SNP) | VAF 81/99 reads (82%) | catalogued as rs777382241, COSV54114467; called by muse, mutect2, varscan2
- BIRC8 | n.1376C>A | RNA (SNP) | VAF 77/83 reads (93%) | catalogued as COSV101461305; called by muse, mutect2, varscan2
- BIRC8 | n.1375C>A | RNA (SNP) | VAF 79/85 reads (93%) | catalogued as rs753010968, COSV101461306; called by muse, mutect2, varscan2
- XIST | n.7378T>C | RNA (SNP) | VAF 12/201 reads (6%) | catalogued as rs1353264824; called by muse, mutect2
